Somatic mutation profile of tumor specimen TCGA-BR-6564-01A (aliquot TCGA-BR-6564-01A-12D-1882-08) from TCGA case TCGA-BR-6564, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 46.9 years (17,129 days).
Specimen TCGA-BR-6564-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3cfecc7-78cd-48d5-b54d-2bef154ff625.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6564-10A (Blood Derived Normal), aliquot TCGA-BR-6564-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc97f61a-1d9e-4420-97b9-c0046b121592

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 13, Silent 10, Nonsense Mutation 3, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1081_1092del p.R361_L364del | In Frame Del (DEL) | VAF 14/101 reads (14%) | hotspot (GDC flag); called by mutect2, pindel
- ARMC8 | c.1267C>T p.Q423* (on ENST00000469044 / NM_001363941.2; = p.Q409* on NM_015396.6) | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV58622673; called by muse, mutect2, varscan2
- BRD8 | c.3130C>T p.Q1044* | Nonsense Mutation (SNP) | VAF 10/114 reads (9%) | catalogued as COSV54731940; called by muse, mutect2
- C3 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771305132, COSV55573413; called by muse, mutect2, varscan2
- CPAMD8 | c.1280C>T p.T427M (on ENST00000651564; = p.T380M on NM_015692.5) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs183563770, COSV52237911; called by muse, mutect2, varscan2
- FAM83G | c.2452C>T p.R818W | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); catalogued as rs765570800, COSV58760294; called by muse, mutect2, varscan2
- LHX8 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV53956548; called by muse, mutect2, varscan2
- MED12 | c.5591C>A p.P1864Q | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.013); catalogued as COSV61355537; called by muse, mutect2, varscan2
- MIER3 | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61230086; called by muse, mutect2, varscan2
- MRGPRX2 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 45/410 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as COSV61674009, COSV61674606; called by muse, mutect2, varscan2
- NECAP1 | c.110A>T p.K37I | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV60250509; called by muse, mutect2
- PDHX | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as rs202188706, COSV57165033, COSV57169068; called by muse, mutect2
- SLC25A53 | c.286T>A p.F96I | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62460820; called by muse, mutect2, varscan2
- SPDEF | c.483G>A p.W161* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV65001751; called by muse, mutect2, varscan2
- TMEM143 | c.1283T>C p.M428T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV53158886; called by muse, mutect2, varscan2
- ZCCHC8 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV60319936; called by muse, mutect2, varscan2
- ZNF75A | c.350T>G p.F117C | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV73039710; called by muse, mutect2, varscan2
- SLC9A4 | c.1679dup p.T561Dfs*27 | Frame Shift Ins (INS) | VAF 17/152 reads (11%) | called by mutect2, pindel, varscan2
- AMOT | c.1809G>A p.V603= (on ENST00000371959 / NM_001113490.1; = p.V194= on NM_133265.3) | Silent (SNP) | VAF 10/149 reads (7%) | catalogued as COSV100495610, COSV59068218; called by muse, mutect2
- ATRNL1 | c.2736G>A p.T912= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as rs782603250, COSV58115307; called by muse, mutect2, varscan2
- ELAC2 | c.1350G>A p.A450= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs375565327; called by muse, mutect2, varscan2
- FRMPD4 | c.2904G>A p.S968= | Silent (SNP) | VAF 27/180 reads (15%) | catalogued as rs768684415, COSV66216485, COSV66223530; called by muse, mutect2, varscan2
- KHSRP | c.1125C>G p.P375= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV67920405; called by muse, mutect2
- OFD1 | c.108C>T p.L36= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV60796411, COSV60798975; called by muse, mutect2
- PRAMEF17 | c.1155C>T p.R385= | Silent (SNP) | VAF 28/311 reads (9%) | catalogued as rs748804075, COSV65816666; called by muse, mutect2
- SLC38A4 | c.948T>C p.H316= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV56971459; called by muse, mutect2
- TENT4B | c.1554T>C p.Y518= (on ENST00000561678 / NM_001365323.2; = p.Y503= on NM_001040284.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/177 reads (14%) | catalogued as rs767230719, COSV62546041; called by muse, mutect2, varscan2
- ZFX | c.1326G>A p.R442= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as COSV58449913; called by muse, mutect2, varscan2
